Somatic mutation profile of tumor specimen TCGA-CZ-4865-01A (aliquot TCGA-CZ-4865-01A-02D-1501-10) from TCGA case TCGA-CZ-4865, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.4 years (25,709 days).
Specimen TCGA-CZ-4865-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d7331d6-789b-4999-89c2-ac81a8c78e00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-4865-11A (Solid Tissue Normal), aliquot TCGA-CZ-4865-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d96d9acc-1620-49e4-a0db-203b90ae0af9

The open-access MAF lists 89 somatic variants for this specimen: 72 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Frame Shift Del 7, Nonsense Mutation 4, Splice Site 3, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 13/138 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2
- AAGAB | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 100/557 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56016174; called by muse, mutect2, varscan2
- AASDHPPT | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV53788434; called by muse, mutect2, varscan2
- ABCC3 | c.1313T>G p.I438S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV53318080; called by muse, mutect2, varscan2
- ACAD10 | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100563857; called by mutect2, varscan2
- ADGRG4 | c.5757G>C p.L1919F | Missense Mutation (SNP) | VAF 137/423 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99794522; called by muse, mutect2, varscan2
- AHSG | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 81/399 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99889871; called by muse, mutect2, varscan2
- ANKS4B | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1361390215, COSV100289714; called by muse, mutect2
- ARMT1 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV66178406; called by muse, mutect2, varscan2
- CCNK | c.862G>C p.V288L | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV66274254; called by muse, mutect2, varscan2
- CDK2 | c.58A>G p.K20E | Missense Mutation (SNP) | VAF 78/438 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57186078; called by muse, mutect2
- CEP250 | c.244-1G>C p.X82_splice | Splice Site (SNP) | VAF 36/190 reads (19%) | catalogued as COSV61168580; called by muse, mutect2
- CFAP298-TCP10L | c.1037T>C p.I346T | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.245); catalogued as COSV100291814; called by muse, mutect2, varscan2
- CHD6 | c.3142C>A p.P1048T | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100497823; called by muse, mutect2, varscan2
- COL24A1 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65302941; called by muse, mutect2, varscan2
- DHX9 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 72/339 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV62358531; called by muse, mutect2, varscan2
- DIPK2B | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65005080; called by muse, mutect2, varscan2
- EIF4A3 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 73/373 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as COSV53919810; called by muse, mutect2
- FAM162B | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 74/386 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs1206564487, COSV63920120; called by muse, mutect2, varscan2
- FCRL4 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV54860452; called by muse, mutect2, varscan2
- G3BP2 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 113/586 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62975857; called by muse, mutect2, varscan2
- GAN | c.1263G>T p.K421N | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1457060434, COSV73720767; called by muse, mutect2, varscan2
- GGT1 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV50638386; called by muse, mutect2, varscan2
- GRIK5 | c.342+1G>T p.X114_splice | Splice Site (SNP) | VAF 12/72 reads (17%) | catalogued as COSV53475673, COSV53487025; called by muse, mutect2, varscan2
- GZMK | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 71/482 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV50244291; called by muse, mutect2, varscan2
- HECW1 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 22/99 reads (22%) | catalogued as COSV67823839; called by muse, mutect2, varscan2
- HTR2A | c.760T>C p.Y254H | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66326760; called by muse, mutect2, varscan2
- ILDR2 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs765518152, COSV54829316; called by muse, mutect2, varscan2
- ITGB5 | c.1128T>C p.N376= | Splice Region (SNP) | VAF 60/351 reads (17%) | catalogued as rs757555259, COSV56146990; called by muse, mutect2
- ITIH5 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs529878669, COSV53660905; called by muse, mutect2, varscan2
- KCTD18 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV63343989; called by muse, mutect2
- KIF20B | c.3023A>G p.N1008S (on ENST00000371728 / NM_001284259.2; = p.N968S on NM_016195.4) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1215858463, COSV53303439; called by muse, mutect2, varscan2
- KMT2A | c.8435C>A p.T2812K | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV63282923; called by muse, mutect2, varscan2
- LINS1 | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59078120; called by muse, mutect2, varscan2
- LSM14B | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53378891; called by muse, varscan2
- MED12L | c.438A>T p.L146F | Missense Mutation (SNP) | VAF 85/440 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104383577, COSV56371100; called by muse, mutect2, varscan2
- MYH2 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 58/373 reads (16%) | catalogued as COSV55433014; called by muse, mutect2, varscan2
- NAA20 | c.85A>C p.I29L | Missense Mutation (SNP) | VAF 79/470 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV58548171; called by muse, mutect2, varscan2
- NAP1L2 | c.1349A>C p.N450T | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.677); catalogued as COSV65172248; called by muse, mutect2, varscan2
- NDC80 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 84/426 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV55247022, COSV55247195, COSV55248268; called by muse, mutect2, varscan2
- NT5M | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66518523; called by muse, mutect2, varscan2
- OR5B12 | c.527T>A p.F176Y | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56904202; called by muse, mutect2, varscan2
- PAPOLG | c.1072T>C p.S358P | Missense Mutation (SNP) | VAF 104/477 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV99474470; called by muse, mutect2, varscan2
- PHLDB1 | c.727T>A p.S243T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV100616295; called by muse, mutect2, varscan2
- PHLDB1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs781973410, COSV100616297; called by muse, mutect2, varscan2
- PIK3R6 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV61001886; called by muse, mutect2, varscan2
- PKHD1 | c.10126G>T p.A3376S | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV61863951; called by muse, mutect2, varscan2
- PLCE1 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 46/230 reads (20%) | catalogued as COSV53340261; called by muse, mutect2, varscan2
- PLG | c.496A>T p.T166S | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51981251; called by muse, mutect2, varscan2
- PSMD4 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs761401984, COSV64393119; called by muse, mutect2, varscan2
- REPS2 | c.1376C>G p.S459C | Missense Mutation (SNP) | VAF 115/542 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV58179775; called by muse, mutect2, varscan2
- RIPOR2 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52418168; called by muse, mutect2, varscan2
- RLIM | c.642G>C p.R214S | Missense Mutation (SNP) | VAF 72/431 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.477); catalogued as COSV60325528; called by muse, mutect2, varscan2
- SFRP4 | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV71412261; called by muse, mutect2
- SNRNP40 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.63); catalogued as COSV55276509; called by muse, mutect2, varscan2
- SPEN | c.2588A>C p.D863A | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65358648, COSV65361286; called by muse, mutect2, varscan2
- STK31 | c.2531C>G p.T844R | Missense Mutation (SNP) | VAF 86/508 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63454484; called by muse, mutect2, varscan2
- TMEM106A | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV57831131; called by muse, mutect2, varscan2
- TMEM17 | c.319-1G>C p.X107_splice | Splice Site (SNP) | VAF 30/122 reads (25%) | catalogued as COSV59022454; called by muse, mutect2
- TTK | c.2024C>A p.T675K | Missense Mutation (SNP) | VAF 128/643 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV57882191; called by muse, mutect2, varscan2
- TUBGCP3 | c.2164A>G p.I722V | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV56184740; called by muse, mutect2
- UCK2 | c.115A>T p.K39* | Nonsense Mutation (SNP) | VAF 73/302 reads (24%) | catalogued as COSV63314590; called by muse, mutect2, varscan2
- ULK3 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51510389; called by muse, mutect2, varscan2
- AKAP12 | c.816del p.K272Nfs*17 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- ELOC | c.334del p.C112Vfs*3 | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- FAT4 | c.10767_10773delinsA p.D3590_S3591del | In Frame Del (DEL) | VAF 23/74 reads (31%) | called by pindel, varscan2*
- HECTD4 | c.12605G>T p.S4202I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.182); called by muse, mutect2
- MPP5 | c.191del p.E64Gfs*3 | Frame Shift Del (DEL) | VAF 57/278 reads (21%) | called by mutect2, pindel, varscan2
- NCAPG2 | c.1483del p.W495Gfs*25 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- NR2F2 | c.766_767del p.N256Cfs*52 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- SPEN | c.1922_1923del p.T641Ifs*3 | Frame Shift Del (DEL) | VAF 32/177 reads (18%) | called by mutect2, pindel, varscan2
- YEATS4 | c.472del p.S158Lfs*4 | Frame Shift Del (DEL) | VAF 64/416 reads (15%) | called by mutect2, pindel*, varscan2
- CARMIL2 | c.342C>T p.A114= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV58023832; called by muse, mutect2
- DMRTC1 | c.492G>A p.Q164= | Silent (SNP) | VAF 14/224 reads (6%) | called by muse, varscan2
- EPB41L3 | c.1017G>A p.K339= | Silent (SNP) | VAF 49/300 reads (16%) | catalogued as COSV59446459; called by muse, mutect2, varscan2
- FUT10 | c.828T>C p.F276= | Silent (SNP) | VAF 43/183 reads (23%) | catalogued as COSV59450200; called by muse, mutect2, varscan2
- GTSF1 | c.213T>C p.C71= | Silent (SNP) | VAF 68/328 reads (21%) | catalogued as rs1202221923, COSV59938359; called by muse, mutect2
- LVRN | c.2373G>A p.A791= | Silent (SNP) | VAF 126/626 reads (20%) | catalogued as rs763520683, COSV63496414; called by muse, mutect2, varscan2
- LYST | c.9375T>C p.Y3125= | Silent (SNP) | VAF 100/554 reads (18%) | catalogued as rs907065551, COSV67704102; called by muse, mutect2
- MED18 | c.105C>T p.L35= | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as rs756815952, COSV65790330; called by muse, mutect2, varscan2
- MTCP1 | c.21G>A p.G7= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100749852; called by muse, mutect2, varscan2
- OR7G3 | c.771G>A p.G257= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as rs763249942, COSV59640020; called by muse, mutect2, varscan2
- PRLHR | c.453G>T p.T151= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, varscan2
- SDK1 | c.1620C>A p.I540= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs774589584, COSV101268838; called by muse, mutect2, varscan2
- TICRR | c.1212C>T p.P404= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV51538706; called by muse, mutect2, varscan2
- UGT2B4 | c.93A>G p.T31= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as COSV59315661; called by muse, mutect2
- UNC5C | c.2130C>G p.A710= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV101497799; called by muse, mutect2
- USP25 | c.2697C>T p.F899= | Silent (SNP) | VAF 167/835 reads (20%) | catalogued as rs771333405, COSV53481876; called by muse, mutect2, varscan2
- DCHS2 | n.6890del | RNA (DEL) | VAF 43/228 reads (19%) | called by mutect2, pindel, varscan2
